MMRF case MMRF_2401 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2ff5c839-e056-4fcc-a4a5-43f11535024e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Dead; Days to death: 389 days (1.1 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.5 years (23,552 days); ISS stage: III; Days to last known disease status: 389 days (1.1 years); Days to last follow up: 389 days (1.1 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 99 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 98 days.
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 14 days.
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 15 days; Days to treatment end: 115 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 123 days; Days to treatment end: 249 days.
   Treatment given: Therapeutic agents: Dexamethasone + Doxorubicin + Melphalan + Other; Regimen or line of therapy: Third line of therapy; Days to treatment start: 251 days; Days to treatment end: 270 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Third line of therapy; Days to treatment start: 271 days; Days to treatment end: 272 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Third line of therapy; Days to treatment start: 274 days; Days to treatment end: 274 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 295 days; Days to treatment end: 298 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 305 days; Days to treatment end: 364 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 305 days; Days to treatment end: 350 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 389.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3: M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1090 mg/dL; Immunoglobulin G 5.54 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 7.22 µg/mL; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 12.1 ×10⁹/L; Absolute Neutrophil 8.8 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 332 µmol/L; Blood Urea Nitrogen 18.6 mmol/L; Calcium 3.53 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 13.4 mmol/L; C-Reactive Protein 1.73 mg/dL.
- Day 88: M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.926 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1280 mg/dL; Immunoglobulin G 2.89 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.6 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 6.71 mmol/L.
- Day 165 (ECOG 0): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.526 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 407 mg/dL; Immunoglobulin G 2.84 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 4.32 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.38 mmol/L; Albumin 44 g/L; Total Protein 6.1 g/dL; Glucose 6.33 mmol/L.
- Day 281 (ECOG 3): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.475 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1500 mg/dL; Immunoglobulin G 2.59 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 7 µg/mL; Lactate Dehydrogenase 3.85 µkat/L; Hemoglobin 5.64 mmol/L; Absolute Neutrophil 0 ×10⁹/L; Platelets 11 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.1 mmol/L; Albumin 32 g/L; Total Protein 4.5 g/dL; Glucose 11.6 mmol/L.
- Day 365: M Protein 0.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.919 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 94.5 mg/dL; Immunoglobulin G 4.93 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.02 g/L; Beta 2 Microglobulin 4.36 µg/mL; Lactate Dehydrogenase 4.38 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 76 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.13 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 4.62 mmol/L.

Other clinical attributes
- Day -3: Weight: 67 kg; Height: 169 cm.

Biospecimens (4 samples)
- Sample MMRF_2401_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_2401_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
- Sample MMRF_2401_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
- Sample MMRF_2401_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 88 days.
